Surgical pathology report (de-identified scan), TCGA case TCGA-VT-A80J, project TCGA-SARC (Sarcoma), tissue source site Vanderbilt, specimen TCGA-VT-A80J-01A (Primary Tumor).

[page 1 of 4]
YOF

Final Report

ICD O-3

Sarcoma, undifferentiated
pleomorphic (8805/3)

(8802/3) Code to highest 8805/3

Site @ Leg NOS C49.2

Sp 1/17/14

DIAGNOSIS:

1-4) SOFT TISSUE, PROXIMAL FASCIA MARGIN, LATERAL FASCIA MARGIN, DISTAL FASCIA MARGIN AND MEDIAL FASCIAL MARGIN, BIOPSIES: NEGATIVE FOR MALIGNANCY.

5) LEFT LEG, AMPUTATION: UNDIFFERENTIATED PLEOMORPHIC SARCOMA, FNCLCC GRADE

3, MULTIPLE NODULES (SEE SUMMARY FINDINGS).

Soft Tissue Tumors Summary of Findings
(Non-Ewing sarcoma/PNET, Non-rhabdomyosarcoma)
Based on AJCC/UICC TNM, 7th edition

Procedure: Radical resection

Tumor Site: left leg

Tumor Size: 9.0 cm

*Additional dimensions: 5.0 x 2.0 cm

Macroscopic Extent of Tumor: Superficial; subcutaneous/suprafascial

Histologic Type (World Health Organization classification of soft tissue

tumors): UNDIFFERENTIATED PLEOMORPHIC SARCOMA

Mitotic Rate: 41/10 high-power fields (HPF)

(1 HPF x 400 = 0.1734 mm²; X40 objective; most proliferative area)

Necrosis (macroscopic or microscopic): Present; <50%

Histologic Grade (French Federation of Cancer Centers Sarcoma Group [FNCLCC]): Grade 3

Surgical resection margins: Negative

Distance of sarcoma from closest margin: 3.0 cm

Specify margin: proximal

Residual Tumor (R)

R0 No residual tumor

*Lymph-Vascular Invasion: Not identified

AJCC/UICC Pathologic Staging (pTNM), 7th edition: Stage IIB

Primary Tumor (pT)

pT2a: Tumor more than 5 cm in greatest dimension, superficial tumor

Regional Lymph Nodes (pN)

pNX: Regional lymph nodes cannot be assessed

Number examined: 0

Number positive: 0

Distant Metastasis (pM)

[page 2 of 4]
Not applicable

Ancillary Studies

Immunohistochemistry: Not performed

Cytogenetics: Not performed

Molecular Pathology: Not performed

Pre-resection Treatment: No therapy

Treatment Effect: N/A

CLINICAL DATA

Clinical Features: Sarcoma

Operator:

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) Proximal fascia margin; 2) Lateral
fascia margin; 3) distal fascia margin;
4) medial fascial margin; 5) left leg

GROSS DESCRIPTION:

1) SOURCE: Proximal Fascia Margin

Received fresh in a container labeled with the patient's name and medical record number and "proximal fascia margin" is a piece of red-white glistening soft tissue (1.3 x 1.0 x 0.3 cm). The specimen is submitted entirely for frozen section analysis.
Summary of sections: 1AFSC, 1/1.

2) SOURCE: Lateral Fascia Margin

Received fresh in a container labeled with the patient's name and medical record number and "lateral fascia margin" is a piece of yellow soft tissue (1.2 x 0.5 x 0.3 cm). The specimen is submitted entirely for frozen section analysis.
Summary of sections: 2AFSC, 1/1.

3) SOURCE: Distal Fascia Margin

Received fresh labeled with the patient's name and "distal fascial margin" is a 1.5 x 0.2 x 0.2 cm tan-pink and smooth piece of fascia. The specimen is entirely frozen and submitted as 3AFSC 1/1.

[page 3 of 4]
4) SOURCE: Medial Fascia Margin

Received fresh labeled with the patient's name and "medial fascia margin"
is a tan-pink, smooth, piece of fascia which is 1.2 x 0.2 x 0.2 cm. The specimen is frozen and entirely submitted as 4AFSC 1/1.

Summary of sections: /1.

5) SOURCE: Left Leg

Received fresh is a below knee amputation. The foot is 23 cm in length. The lower leg is 38 cm in length with protruding 1.5 cm of tibia and 4.0 cm of fibula. The skin over the foot is tan-pink, grossly unremarkable. Three subcutaneous nodules with tan, light fleshy cut surfaces are present on the anterior midline and lateral aspect of the leg and range in size from 9.0 x 5.0 x 2.0 cm to 0.2 cm. The proximal margin is 3.0 cm from tumor.

Summary of sections:

5A, perineal vascular bundle margin of resection, 1/1;
5B, posterior tibial vascular bundle margin of resection, 2/1;
5C, anterior tibial artery, vascular bundle margin of resection, 2/1;
5D, skin and muscle from the anterior margin of resection, 2/1;
5E, most superior lesion, 1/1;
5F, smallest skin lesion, 1/1;
5G, skin lesion inferior to the main lesion, 1/1;
5J, posterior medial skin and soft tissue margin of resection, 2/1;
5K-O, lesion to fascia, all 1/1;
5P, bone at deepest aspect of the lesion (the bone is 0.5 cm away from the base of the lesion), 1/1, following decalcification;
5Q, fibular margin of resection, 1/1, following decalcification;
5R-S, section of tibial margin of resection, 1/1, following decalcification;

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Proximal Fascia Margin

FROZEN SECTION DIAGNOSIS:

1AFS: PROXIMAL FASCIAL MARGIN, EXCISION: BENIGN.

2) SOURCE: Lateral Fascia Margin

[page 4 of 4]
FROZEN SECTION DIAGNOSIS:

2AFS: LATERAL FASCIAL MARGIN, EXCISION: BENIGN.

3) SOURCE: Distal Fascia Margin

FROZEN SECTION DIAGNOSIS:

3AFS: DISTAL FASCIAL MARGIN, EXCISION: BENIGN.

4) SOURCE: Medial Fascia Margin

FROZEN SECTION DIAGNOSIS:

4AFS: MEDIAL FASCIAL MARGIN, EXCISION: BENIGN.

The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report above:
1xDECALCIFICATION, 4xDECALCIFICATION OF BLOCK

In some tests, analyte specific reagents (ASRs) are used. In the case of an ASR, this test was developed and its performance characteristics determined by this laboratory. It has not been cleared or approved by the

US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file fc471202-8f20-4d36-bec0-f025b15c6945 (TCGA-VT-A80J.8B10CFF2-7584-4E05-95F9-9073E318394B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).